Somatic mutation profile of tumor specimen ALCH-B4UX-TTP1-A (aliquot ALCH-B4UX-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4UX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.1 years (25,964 days).
Specimen ALCH-B4UX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a05643cf-4e39-402b-9005-17cd8fa51955.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4UX-NB1-A (Blood Derived Normal), aliquot ALCH-B4UX-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8b9aafb-1821-4afc-9f1b-8d2c589d4de3

The open-access MAF lists 42 somatic variants for this specimen: 32 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 7, Intron 3, Frame Shift Del 2, In Frame Del 1, Translation Start Site 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB8 | c.496C>T p.P166S (on ENST00000297504 / NM_001282291.2; = p.P149S on NM_007188.5) | Missense Mutation (SNP) | VAF 39/276 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52504040; called by muse, mutect2, varscan2
- ATP2C2 | c.1412G>A p.S471N | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs780581604; called by muse, mutect2
- CCDC189 | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 28/161 reads (17%) | catalogued as rs373334034; called by muse, mutect2, varscan2
- CCNA1 | c.236C>G p.P79R | Missense Mutation (SNP) | VAF 44/324 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV55220447; called by muse, mutect2, varscan2
- DCAF12L2 | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs772875857; called by muse, mutect2, varscan2
- FLYWCH1 | c.1130G>A p.G377D (on ENST00000253928 / NM_001308068.2; = p.G376D on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/309 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs373786669; called by muse, mutect2, varscan2
- FSIP2 | c.18583C>T p.P6195S | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV58088167; called by muse, mutect2
- MTSS2 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 91/551 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs776729070; called by muse, mutect2, varscan2
- MYOC | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 138/862 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as rs1351097164, COSV50677257; called by muse, mutect2, varscan2
- PCDHB8 | c.1684G>A p.V562M | Missense Mutation (SNP) | VAF 82/1027 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV50753540; called by muse, mutect2
- PIWIL1 | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 95/607 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55352084; called by muse, mutect2, varscan2
- PTPN14 | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 90/810 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as rs778272936, COSV100872311; called by muse, mutect2, varscan2
- RPRD1A | c.813_814del p.R271Sfs*40 | Frame Shift Del (DEL) | VAF 84/618 reads (14%) | catalogued as rs754729592; called by pindel, varscan2
- SH3BP5 | c.185G>C p.R62P | Missense Mutation (SNP) | VAF 40/294 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); catalogued as rs1337230406; called by muse, mutect2, varscan2
- ZNF469 | c.3719C>T p.P1240L (on ENST00000437464; = p.P1268L on NM_001367624.2) | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV71259240; called by muse, mutect2, varscan2
- ADAMTS10 | c.891C>A p.D297E | Missense Mutation (SNP) | VAF 44/358 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.423); called by mutect2, varscan2
- ANKRD30BL | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- ASXL1 | c.2762C>G p.S921C | Missense Mutation (SNP) | VAF 160/1154 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- COL19A1 | c.187T>C p.F63L | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- COMT | c.538_541dup p.D181Vfs*2 | Frame Shift Ins (INS) | VAF 95/695 reads (14%) | called by mutect2, pindel, varscan2
- CUBN | c.5450C>G p.P1817R | Missense Mutation (SNP) | VAF 99/767 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- EEF1B2 | c.268A>C p.S90R | Missense Mutation (SNP) | VAF 78/684 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- GON7 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- MAP1LC3B | c.332T>C p.M111T | Missense Mutation (SNP) | VAF 48/392 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NOS1 | c.190_207del p.I64_G69del | In Frame Del (DEL) | VAF 36/240 reads (15%) | called by mutect2, pindel, varscan2
- OR2F2 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 69/426 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RALGAPA2 | c.806A>G p.D269G | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- RNF213 | c.1349A>G p.Y450C | Missense Mutation (SNP) | VAF 77/663 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA3E | c.658C>A p.R220S | Missense Mutation (SNP) | VAF 67/569 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- SNX7 | c.373G>C p.G125R | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.456); called by muse, mutect2
- ZFHX2 | c.3287C>A p.A1096D | Missense Mutation (SNP) | VAF 32/332 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.221); called by muse, mutect2
- ZNF790 | c.1041del p.F347Lfs*7 | Frame Shift Del (DEL) | VAF 13/95 reads (14%) | called by pindel, varscan2
- APBA2 | c.1758G>A p.S586= | Silent (SNP) | VAF 42/244 reads (17%) | catalogued as rs754605894; called by muse, mutect2, varscan2
- DNAH10 | c.6318G>A p.V2106= (on ENST00000409039; = p.V2045= on NM_207437.3) | Silent (SNP) | VAF 69/432 reads (16%) | catalogued as COSV101293142, COSV68996430; called by muse, mutect2, varscan2
- DOP1B | c.4482C>G p.T1494= | Silent (SNP) | VAF 27/193 reads (14%) | called by muse, mutect2, varscan2
- IGFN1 | c.3663G>A p.P1221= (on ENST00000295591 / NM_001367841.1; = p.P3678= on NM_001164586.2) | Silent (SNP) | VAF 64/406 reads (16%) | catalogued as rs749503568; called by muse, mutect2, varscan2
- MUC3A | c.7197C>G p.T2399= | Silent (SNP) | VAF 75/418 reads (18%) | catalogued as rs751841125; called by muse, mutect2, varscan2
- PTGES3 | c.231A>G p.L77= | Silent (SNP) | VAF 14/175 reads (8%) | called by muse, mutect2
- RABIF | c.216G>A p.E72= | Silent (SNP) | VAF 53/453 reads (12%) | called by muse, mutect2, varscan2
- BLK | c.1030-111A>G | Intron (SNP) | VAF 48/392 reads (12%) | called by muse, mutect2, varscan2
- SCD5 | c.569+19706G>C | Intron (SNP) | VAF 93/706 reads (13%) | called by muse, mutect2, varscan2
- SPART | c.-3+4540G>A | Intron (SNP) | VAF 26/190 reads (14%) | catalogued as rs557936993; called by muse, mutect2, varscan2
